Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3845, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3845-01A (Primary Tumor).

Diagnosis:

This is a poorly differentiated solid carcinoma in the ascending colon of histopathological differentiation grade G3, with necrosis, with ulceration of the inner tumor surface, with peritumorous chronic recurrent secondary inflammation with acute inflammatory activity, with carcinomatous lymphangitis, with tumor infiltration of the layers of the colon wall extending to the extramuscular subserous fatty connective tissue, with tumor-free lymph nodes (0/12) and also tumor-free overview slices from all other portions of the preparation described. No evidence of serous carcinosis.

The tumor spread of the colon carcinoma according to the section preparations available corresponds to a tumor stage of pT3, pN0 (0/12), MX, L1, R0

Tumor classification:

ICDO-DA M-8140/3, G3

Source: NCI Genomic Data Commons file c0fb889c-20aa-49cc-b3d7-478060292c34 (TCGA-AA-3845.AFFF68AF-721B-4271-8C94-1C071BB75321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).